Somatic mutation profile of tumor specimen MMRF_1628_1_BM_CD138pos (aliquot MMRF_1628_1_BM_CD138pos_T2_KBS5U_K11922) from MMRF case MMRF_1628, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.7 years (23,277 days).
Specimen MMRF_1628_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa8eaae-521d-4edd-9e63-93422edb5e26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1628_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1628_1_PB_Whole_C7_KBS5U_K11901; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c580a13-2bf4-42f6-9c12-00b5d598da63

The open-access MAF lists 136 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 38, Intron 14, Silent 13, 5'UTR 12, RNA 3, Frame Shift Del 3, 3'Flank 3, 5'Flank 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMSAP1 | c.4220C>T p.A1407V | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); catalogued as rs1423111711; called by muse, mutect2, varscan2
- CDRT15L2 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV67568618; called by muse, mutect2, varscan2
- CFAP161 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs765348041; called by muse, mutect2, varscan2
- CNR1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as rs755180172; called by muse, mutect2, varscan2
- COL18A1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs746954871; called by muse, mutect2, varscan2
- FAT1 | c.4804G>C p.E1602Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV101499677; called by muse, mutect2, varscan2
- GGH | c.144G>C p.M48I | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99478882; called by muse, mutect2
- KAT2B | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as rs1356312243, COSV55429637; called by muse, mutect2, varscan2
- KCNH1 | c.2942C>T p.S981L (on ENST00000271751 / NM_172362.3; = p.S954L on NM_002238.4) | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs145248227; called by muse, mutect2, varscan2
- KCNH8 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379582412, COSV60460065; called by muse, mutect2, varscan2
- LARP6 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.92); catalogued as rs1470794444, COSV100150959; called by muse, mutect2, varscan2
- NCOR1 | c.2131G>T p.D711Y | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52003415; called by muse, mutect2, varscan2
- NXN | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767391651, COSV100402928; called by muse, mutect2, varscan2
- RTP1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1418244179; called by muse, mutect2
- SARDH | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs761758590; called by muse, mutect2, varscan2
- SH3RF2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs760745037; called by muse, mutect2, varscan2
- STAB1 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs200132959; called by muse, mutect2, varscan2
- SYT13 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs368306910; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53431488; called by muse, varscan2
- TSPOAP1 | c.4253G>A p.R1418H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs749779228; called by muse, mutect2, varscan2
- TTBK1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs745618169, COSV52491503; called by muse, mutect2, varscan2
- CCDC62 | c.1744T>A p.S582T | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CD33 | c.500G>C p.W167S | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CNDP2 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.696); called by muse, mutect2
- DENND5A | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKB | c.2273T>C p.I758T | Missense Mutation (SNP) | VAF 103/257 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DOP1B | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM53A | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- GSDMA | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HUS1B | c.19A>C p.I7L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGKJ1 | c.2del p.W2Gfs*? | Frame Shift Del (DEL) | VAF 86/94 reads (91%) | called by mutect2, pindel*, varscan2
- IGKV3-20 | chr2:89142573 GAGGT>TG | Missense Mutation (DEL) | VAF 18/71 reads (25%) | called by pindel, varscan2*
- JPH1 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1522 | c.2138C>T p.P713L (on ENST00000373480 / NM_001198972.2; = p.P772L on NM_020888.3) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KLHL32 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- LRRC15 | c.1595T>C p.M532T | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYDGF | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- OTOGL | c.2435G>C p.G812A (on ENST00000547103; = p.G803A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- PBLD | c.84T>G p.N28K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIGN | c.2194_2197del p.F732Hfs*2 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- PRRC2B | c.2719del p.S907Afs*41 | Frame Shift Del (DEL) | VAF 65/271 reads (24%) | called by mutect2, pindel, varscan2
- RIC3 | c.902A>G p.E301G (on ENST00000309737 / NM_001206671.4; = p.E300G on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLFN5 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPANXN2 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 254/266 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, varscan2
- TCOF1 | c.1537G>A p.G513S (on ENST00000377797 / NM_001135243.1; = p.G436S on NM_000356.4) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2
- TLN2 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TMEM64 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFSF12 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- UPF3B | c.1255dup p.T419Nfs*2 (on ENST00000276201 / NM_080632.3; = p.T406Nfs*2 on NM_023010.3) | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- ZNF285 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF347 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BMP6 | c.1386G>A p.Q462= | Silent (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- CADM4 | c.615G>A p.A205= | Silent (SNP) | VAF 184/276 reads (67%) | catalogued as rs750404733; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 49/55 reads (89%) | catalogued as rs367953381; called by muse, varscan2
- LAMB1 | c.4296T>C p.G1432= | Silent (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2, varscan2
- LYST | c.4350T>A p.S1450= | Silent (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- PDE3A | c.3348C>T p.I1116= | Silent (SNP) | VAF 99/232 reads (43%) | catalogued as rs139034447; called by muse, mutect2, varscan2
- PLPPR3 | c.1677G>A p.S559= (on ENST00000520876 / NM_001270366.2; = p.S587= on NM_024888.2) | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1373762846, COSV62461963; called by muse, mutect2, varscan2
- SLC5A11 | c.672C>T p.A224= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs553064506; called by muse, mutect2, varscan2
- SPAM1 | c.252C>T p.T84= | Silent (SNP) | VAF 94/179 reads (53%) | catalogued as rs759911125, COSV56149280, COSV99773201; called by muse, mutect2, varscan2
- TSNARE1 | c.1224C>A p.L408= | Silent (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- UROC1 | c.750C>T p.G250= | Silent (SNP) | VAF 115/242 reads (48%) | catalogued as rs577264170; called by muse, mutect2, varscan2
- WWTR1 | c.207G>A p.S69= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ZNF541 | c.1569G>A p.E523= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- ACTR3 | c.*3252T>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- ADAM19 | c.*140T>G | 3'UTR (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*1686_*1697del | 3'UTR (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD60 | chr20:58232727 G>T | 5'Flank (SNP) | VAF 65/158 reads (41%) | called by muse, mutect2, varscan2
- CAND1 | c.*5248G>C | 3'UTR (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
- CAV1 | c.*387T>C | 3'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- CCDC6 | c.*2211C>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- CCDC85B | c.-93G>A | 5'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as COSV57028331; called by muse, mutect2, varscan2
- CCDC92 | c.*927C>T | 3'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as rs1365202519; called by muse, mutect2, varscan2
- CENPO | c.-117G>C | 5'UTR (SNP) | VAF 71/158 reads (45%) | called by muse, mutect2, varscan2
- CERS5 | c.304-294C>G | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- CHST10 | c.-104+502C>A | Intron (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- CLK4 | c.162-1687G>A | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2937638 G>C | 3'Flank (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- DCX | c.*1975A>G | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- DPP10 | c.61-147001G>A | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs533542037; called by muse, mutect2
- DTX1 | c.-398G>A | 5'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- DTX1 | c.-397G>A | 5'UTR (SNP) | VAF 16/42 reads (38%) | catalogued as rs1395771067; called by muse, mutect2, varscan2
- EID2 | c.*628A>C | 3'UTR (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- EIF3J | c.571+88G>C | Intron (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- FAM221A | chr7:23680174 G>C | 5'Flank (SNP) | VAF 22/38 reads (58%) | catalogued as rs938733618; called by muse, mutect2
- FGD4 | c.*2150A>C | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2
- FGF7 | c.*2623T>C | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, varscan2
- FITM2 | c.*2350C>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- FLRT2 | c.*3905G>T | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- FOXR1 | c.-133G>A | 5'UTR (SNP) | VAF 10/140 reads (7%) | catalogued as rs1399833949; called by muse, mutect2
- GJB4 | c.*58A>C | 3'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as rs1226006409; called by muse, mutect2
- GLRA2 | c.-12A>G | 5'UTR (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- GRAP2 | c.-233G>C | 5'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- GUCA1A | c.*45G>A | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- HHIP | c.*424dup | 3'UTR (INS) | VAF 23/57 reads (40%) | catalogued as rs970973565; called by mutect2, varscan2
- IRS1 | c.-205G>A | 5'UTR (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- KIF5A | c.1570-25G>A | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- KRT80 | c.570+141_571-147del | Intron (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- LIN9 | c.244+300G>A | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs1194057298; called by muse, mutect2, varscan2
- LINC02869 | n.325T>G | RNA (SNP) | VAF 91/207 reads (44%) | called by muse, mutect2, varscan2
- MAGEE2 | c.*2G>T | 3'UTR (SNP) | VAF 26/26 reads (100%) | catalogued as COSV100972992; called by muse, mutect2, varscan2
- MKNK1 | c.*618T>C | 3'UTR (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- NAPEPLD | c.*1995C>T | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- NAT8L | c.*739G>A | 3'UTR (SNP) | VAF 15/61 reads (25%) | catalogued as rs1310154428; called by muse, mutect2, varscan2
- NCOA3 | c.*165T>A | 3'UTR (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- OR9Q2 | c.-5G>T | 5'UTR (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2394+1824T>G | Intron (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- PEAK1 | c.*1936C>G | 3'UTR (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1719+2313C>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PITPNB | c.*1287T>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | catalogued as rs1410064946; called by muse, varscan2
- PKMYT1 | c.10+73G>T | Intron (SNP) | VAF 16/98 reads (16%) | catalogued as rs1232936158; called by muse, mutect2, varscan2
- POU6F2 | chr7:39468264 G>C | 3'Flank (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*1628dup | 3'UTR (INS) | VAF 44/77 reads (57%) | catalogued as rs900549327; called by mutect2, varscan2
- RANBP17 | c.*691G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- REM2 | c.727+79C>A | Intron (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- RNF217-AS1 | n.3018A>G | RNA (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- RTL10 | c.*4755G>C | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- RTL10 | c.*4517G>C | 3'UTR (SNP) | VAF 20/75 reads (27%) | called by muse, varscan2
- RTL10 | c.*4466G>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | catalogued as COSV60735910; called by muse, varscan2
- SCARB1 | c.*153C>T | 3'UTR (SNP) | VAF 25/84 reads (30%) | catalogued as rs761314422; called by muse, mutect2, varscan2
- SLC25A36 | c.*1053A>G | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- SLC36A2 | c.*130G>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SLC41A1 | c.-614C>A | 5'UTR (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624159 A>G | 3'Flank (SNP) | VAF 88/92 reads (96%) | called by muse, varscan2
- SP2 | c.-26C>T | 5'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as rs919948264; called by muse, mutect2
- SPATA31C1 | n.2771C>A | RNA (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- SYT11 | c.*3144T>A | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- TNRC6B | c.*9433dup | 3'UTR (INS) | VAF 24/66 reads (36%) | catalogued as rs556852730; called by mutect2, varscan2
- TPH2 | c.609-10955T>G | Intron (SNP) | VAF 75/157 reads (48%) | called by muse, mutect2, varscan2
- TSPAN17 | c.-99_-71del | 5'UTR (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel
- TXNDC5 | c.*33C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- VGLL3 | c.*7714T>C | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- WDR70 | c.1093-9716_1093-9711del | Intron (DEL) | VAF 58/170 reads (34%) | called by mutect2, pindel, varscan2
- ZNF395 | c.*2142T>C | 3'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- ZNF410 | c.*267A>T | 3'UTR (SNP) | VAF 175/376 reads (47%) | called by muse, mutect2, varscan2
- ZNF703 | c.*697C>T | 3'UTR (SNP) | VAF 27/92 reads (29%) | catalogued as rs1425639506; called by muse, mutect2, varscan2
